Gene-level copy-number profile of tumor specimen TCGA-G4-6299-01A from TCGA case TCGA-G4-6299, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.3 years (25,318 days).
Specimen TCGA-G4-6299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.81ace5b7-c0ae-4d19-b6ff-ce3f0090a81b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6299-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe8d9b2c-1213-47f3-8e1b-9fa79cd9bca1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 3,139; copy number 2: 30,371; copy number 3: 17,795; copy number 4: 7,151; copy number 5: 424; copy number 6: 786; copy number 7: 33; copy number 8: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6299-01A-11D-1770-01): tumor purity 0.54, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:151,883,711–151,943,933, 4 genes (within-gene range 0–2): AC112242.2, AC112242.1, AC097375.2, AC097375.1.
- chr8:39,743,735–40,897,833, 17 genes (within-gene range 0–2): ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,337 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:39,404,590–46,000,898, 137 genes, copy number 5 (broad region; genes not listed).
- chr7:47,252,139–51,864,798, 54 genes, copy number 5: AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2.
- chr7:52,493,152–57,837,046, 173 genes, copy number 5–6 (broad region; genes not listed).
- chr8:76,162,119–97,358,478, 316 genes, copy number 6 (broad region; genes not listed).
- chr8:103,500,696–104,256,094, 1 gene, copy number 5 (within-gene range 3–5): RIMS2.
- chr8:104,330,324–104,589,024, 7 genes, copy number 5: DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2.
- chr8:104,699,479–104,703,555, 1 gene, copy number 5: AC012564.1.
- chr8:115,950,511–116,325,062, 1 gene, copy number 7 (within-gene range 4–7): LINC00536.
- chr8:116,289,622–117,540,262, 17 genes, copy number 7: AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16.
- chr8:119,557,086–131,432,869, 183 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr9:35,406,755–37,075,792, 69 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:67,750,284–72,626,191, 126 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:42,968,743–46,308,498, 132 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:54,475,593–60,814,211, 120 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
